Somatic mutation profile of tumor specimen TCGA-DJ-A2PQ-01A (aliquot TCGA-DJ-A2PQ-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2PQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 26.5 years (9,664 days).
Specimen TCGA-DJ-A2PQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0baf1b87-b4b8-47a6-a190-eeaddff3fd83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PQ-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PQ-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfe8686a-f3cf-4c0b-9d19-ba81cd3bac13

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ZNF598 | c.323_328del p.Y108_A109del | In Frame Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- FBF1 | c.3279C>T p.L1093= (on ENST00000586717; = p.L1108= on NM_001319193.1) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs752564360, COSV59864373; called by muse, mutect2, varscan2
- OR7C2 | c.486C>A p.T162= | Silent (SNP) | VAF 93/231 reads (40%) | catalogued as COSV50180399; called by muse, mutect2, varscan2
